Gene-level copy-number profile of tumor specimen TCGA-KK-A6E1-01A from TCGA case TCGA-KK-A6E1, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.7 years (21,063 days).
Specimen TCGA-KK-A6E1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.32eb09f7-c35a-4627-8120-ff4d5cc6e27e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KK-A6E1-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a31b1bb8-8976-4a8e-b596-10881aebfe53

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 24; copy number 2: 11,168; copy number 3: 6,548; copy number 4: 41,749; copy number 6: 12; copy number 7: 8; copy number 8: 19; copy number 10: 59; copy number 13: 31; copy number 15: 42; copy number 16: 12; copy number 19: 11; copy number 21: 57; copy number 23: 70.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KK-A6E1-01A-11D-A30W-01): tumor purity 0.66, ploidy 3.55, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 282 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:125,969,160–127,680,926, 48 genes, copy number 10: ROPN1B, SLC41A3, AC117422.1, AC079848.1, ALDH1L1, ALDH1L1-AS1, RNU1-30P, ALDH1L1-AS2, AC079848.2, AC016924.1, AC063919.1, AC063919.2, KLF15, CCDC37-DT, CFAP100, AC073439.1, ZXDC, UROC1, CHST13, C3orf22, RNA5SP138, TXNRD3, AC024558.1, NUP210P1, AC078867.1, CHCHD6, RCC2P4, AC011199.1, PLXNA1, AC112482.2, C3orf56, Y_RNA, AC112482.1, RNU6-1047P, AC133681.1, PRR20G, LINC02016, LINC01471, AC016968.1, LINC02034, AC084035.1, TPRA1, MIR6825, MIR7976, MCM2, AC023593.1, PODXL2, ABTB1.
- chr3:128,153,481–128,681,075, 12 genes, copy number 13 (within-gene range 3–13): EEFSEC, AL449214.1, DNAJB8, DNAJB8-AS1, GATA2, GATA2-AS1, TMED10P2, AC080005.1, LINC01565, RPN1, Metazoa_SRP, POU5F1P6.
- chr3:129,001,629–130,035,539, 42 genes, copy number 15: EFCC1, AC108673.1, GP9, RAB43, ISY1-RAB43, AC108673.2, ISY1, AC108673.3, CNBP, RPS27P12, COPG1, MIR6826, AC137695.3, HMCES, H1-10, H1-10-AS1, NUP210P3, AC137695.1, AC137695.2, AL449212.1, RPL32P3, SNORA7B, EFCAB12, MBD4, IFT122, RHO, H1-8, PLXND1, RN7SL752P, AC023162.1, TMCC1, RNY3P13, U6, AC083799.1, TMCC1-AS1, AC083906.3, TRH, AC083906.1, AC083906.5, AC083906.2, OR7E129P, OR7E21P.
- chr3:134,055,256–140,577,397, 100 genes, copy number 13–23 (within-gene range 8–23) (broad region; genes not listed).
- chr3:140,941,830–144,445,844, 68 genes, copy number 10–21 (broad region; genes not listed).
- chr3:146,909,685–147,370,656, 3 genes, copy number 16 (within-gene range 7–16): AC092957.1, LINC02010, RNU6-505P.
- chr4:72,807,267–73,337,771, 9 genes, copy number 16: HNRNPA1P67, RNU4ATAC9P, RNU6ATAC5P, COX18, ANKRD17, HMGA1P2, AC053527.2, AC053527.1, AC108157.1.

Autosomal genes at a single copy (total copy number 1): 24. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
